CCDI case PBCAXU — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/17a4701c-01ae-4e93-b71d-1f6cc52ef454

Demographics
Sex at birth: male; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Dysembryoplastic neuroepithelial tumor: ICD-O-3 morphology code: 9413/0; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.4 years (513 days).

Biospecimens (3 samples)
- Sample 0DN62X: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DN63D: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DN63T: Tissue type: Tumor; Specimen type: Solid Tissue.
